Somatic mutation profile of tumor specimen TCGA-CR-6477-01A (aliquot TCGA-CR-6477-01A-11D-1870-08) from TCGA case TCGA-CR-6477, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; Tumor grade: G2; Age at diagnosis: 57.0 years (20,815 days).
Specimen TCGA-CR-6477-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 096450e1-6c85-4051-a7fd-b03477a07a1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-6477-10A (Blood Derived Normal), aliquot TCGA-CR-6477-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95d6cf69-f552-49e2-b178-e4801f69dea3

The open-access MAF lists 87 somatic variants for this specimen: 66 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 19, Frame Shift Del 7, Nonsense Mutation 5, Frame Shift Ins 2, Translation Start Site 1, Splice Site 1, RNA 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024del p.R342Efs*3 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as rs1131691022, CM004908, COSV52665487; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACSM5 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100088671; called by muse, mutect2
- ACTN3 | c.2524T>C p.F842L | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100074216; called by muse, mutect2, varscan2
- ACVR1 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.304); catalogued as COSV99717663; called by muse, mutect2, varscan2
- AGAP6 | c.907A>G p.I303V (on ENST00000374056 / NM_001365867.1; = p.I326V on NM_001077665.2) | Missense Mutation (SNP) | VAF 50/382 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.022); catalogued as COSV100929066; called by muse, mutect2, varscan2
- AMER1 | c.2230G>C p.A744P | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV100365757; called by muse, mutect2, varscan2
- ANKAR | c.2636-1G>A p.X879_splice | Splice Site (SNP) | VAF 14/61 reads (23%) | catalogued as rs754790948, COSV99854064; called by muse, mutect2, varscan2
- ARHGAP36 | c.856A>C p.N286H | Missense Mutation (SNP) | VAF 67/363 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99357476; called by muse, mutect2, varscan2
- ASPM | c.7594C>T p.H2532Y | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV99660003; called by muse, mutect2, varscan2
- BRWD3 | c.1088A>G p.D363G | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100955862; called by muse, mutect2
- CCDC146 | c.1867A>G p.M623V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV99592398; called by muse, mutect2
- CCNB3 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99328789; called by muse, mutect2
- COL11A1 | c.711G>C p.E237D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100615809; called by muse, mutect2, varscan2
- CPT1A | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs753793488, COSV55754580; called by muse, mutect2
- CSMD1 | c.1846A>C p.I616L (on ENST00000520002; = p.I615L on NM_033225.6) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.941); catalogued as COSV100146048; called by muse, mutect2, varscan2
- CSMD3 | c.7153C>T p.L2385F (on ENST00000297405 / NM_001363185.1; = p.L2281F on NM_052900.3) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99830086; called by muse, mutect2, varscan2
- CUL3 | c.860T>G p.M287R | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100024019; called by muse, mutect2, varscan2
- CYP4A11 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/111 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV100152272; called by muse, mutect2, varscan2
- DHX30 | c.2059C>T p.R687C (on ENST00000445061 / NM_138615.3; = p.R648C on NM_014966.3) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs776310645, COSV99274990; called by muse, varscan2
- DNAH5 | c.12232G>T p.G4078C | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99447579; called by muse, mutect2, varscan2
- DST | c.3749A>G p.Y1250C (on ENST00000361203 / NM_001374722.1; = p.Y924C on NM_001723.6) | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs752803106, COSV99753730; called by muse, mutect2, varscan2
- EPHA3 | c.861T>G p.C287W | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100344193; called by muse, mutect2
- FAT1 | c.6961C>T p.Q2321* | Nonsense Mutation (SNP) | VAF 40/142 reads (28%) | catalogued as COSV71675559; called by muse, mutect2, varscan2
- HIF1A | c.1222A>G p.I408V | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as COSV100048693; called by muse, mutect2, varscan2
- HOXD10 | c.452A>G p.Y151C | Missense Mutation (SNP) | VAF 456/618 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs766860933, COSV50899241; called by muse, mutect2, varscan2
- HTR6 | c.476T>C p.F159S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99230029; called by muse, mutect2, varscan2
- ITFG1 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as rs771169968, COSV100278567, COSV57748677; called by mutect2, varscan2
- ITIH6 | c.2530A>G p.I844V | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99513083; called by muse, mutect2, varscan2
- KCNH7 | c.1412G>A p.R471K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100034992; called by muse, mutect2, varscan2
- LCT | c.3892G>C p.E1298Q | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51556762, COSV99930759; called by muse, mutect2, varscan2
- LRRC8B | c.58T>A p.L20I | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100446485; called by muse, mutect2
- MAPK14 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100004799; called by muse, mutect2, varscan2
- MUC17 | c.8318C>T p.T2773I | Missense Mutation (SNP) | VAF 67/466 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.86); catalogued as COSV100072555; called by muse, mutect2, varscan2
- MYH1 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs780763560, COSV56843727, COSV56851492; called by muse, mutect2, varscan2
- MYO9A | c.2443A>T p.T815S | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100613074; called by muse, mutect2, varscan2
- NAV3 | c.2792G>A p.R931H | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs377644039, COSV99888920; called by mutect2, varscan2
- NUMA1 | c.2788C>T p.Q930* | Nonsense Mutation (SNP) | VAF 26/98 reads (27%) | catalogued as COSV100705992; called by muse, mutect2, varscan2
- PCDH11X | c.2531C>A p.A844D | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV100010458; called by muse, mutect2, varscan2
- PDHA1 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as CM014822, COSV100134448; called by muse, mutect2, varscan2
- PELI2 | c.475G>T p.G159* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99953177; called by muse, mutect2, varscan2
- PPP6R3 | c.1379A>G p.H460R (on ENST00000393800 / NM_001352375.2; = p.H409R on NM_018312.5) | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99676053; called by muse, mutect2, varscan2
- PRAMEF17 | c.349T>G p.S117A | Missense Mutation (SNP) | VAF 44/427 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as COSV101068697; called by muse, mutect2, varscan2
- PSME4 | c.4018C>T p.R1340* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as rs774933375, COSV66368255; called by muse, mutect2
- SAMD11 | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100574573; called by muse, mutect2, varscan2
- SATB1 | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV58672906; called by muse, mutect2, varscan2
- SCN10A | c.3589T>G p.F1197V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101479320, COSV71860710; called by muse, mutect2
- SEC23IP | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV100956807; called by muse, mutect2
- SLC39A6 | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747274757, COSV99309489; called by muse, mutect2, varscan2
- SLC5A1 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs199573966, COSV99833304, COSV99833697; called by muse, mutect2, varscan2
- SLC9C2 | c.1864T>C p.Y622H | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100876668; called by muse, mutect2, varscan2
- ST6GAL2 | c.489T>G p.F163L | Missense Mutation (SNP) | VAF 22/211 reads (10%) | PolyPhen benign (0); catalogued as COSV100867758; called by muse, mutect2, varscan2
- SYT16 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs190756776, COSV101413659, COSV70855911; called by muse, mutect2, varscan2
- TLE4 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54626332, COSV99511678; called by muse, mutect2, varscan2
- TNFRSF4 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99027802; called by muse, mutect2, varscan2
- TRIM51 | c.1129C>A p.L377I | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.04); catalogued as COSV99792383; called by muse, mutect2, varscan2
- UPF3B | c.261G>A p.T87= | Splice Region (SNP) | VAF 7/18 reads (39%) | catalogued as rs749039837, COSV99352069; called by muse, mutect2, varscan2
- ZIC3 | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99798696; called by muse, mutect2, varscan2
- ADAMTSL1 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- ADAMTSL5 | c.794_795del p.T265Rfs*15 | Frame Shift Del (DEL) | VAF 8/75 reads (11%) | called by pindel, varscan2
- ITPR3 | c.2166del p.D722Efs*12 | Frame Shift Del (DEL) | VAF 6/82 reads (7%) | called by mutect2, pindel*
- KDF1 | c.89_90del p.Y30* | Frame Shift Del (DEL) | VAF 34/98 reads (35%) | called by pindel, varscan2
- LZTS2 | c.616_620del p.S206Lfs*96 | Frame Shift Del (DEL) | VAF 49/216 reads (23%) | called by mutect2, pindel, varscan2
- PCDH9 | c.3030_3034del p.R1011Vfs*2 (on ENST00000377865 / NM_203487.3; = p.R1011Vfs*11 on NM_020403.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel, varscan2
- PMPCB | c.1223dup p.M408Ifs*6 | Frame Shift Ins (INS) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- SUSD6 | c.546dup p.G183Wfs*11 | Frame Shift Ins (INS) | VAF 53/140 reads (38%) | called by mutect2, pindel, varscan2
- UMODL1 | c.2403_2407del p.R802Lfs*97 (on ENST00000408910 / NM_001004416.2; = p.R930Lfs*97 on NM_173568.3) | Frame Shift Del (DEL) | VAF 18/95 reads (19%) | called by mutect2, pindel, varscan2
- ABCA3 | c.639C>T p.A213= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs778504757, COSV100068242; called by muse, mutect2, varscan2
- ANKRD13B | c.864G>A p.R288= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV100801174; called by muse, mutect2, varscan2
- C1orf87 | c.729G>A p.K243= | Silent (SNP) | VAF 18/378 reads (5%) | catalogued as COSV100966984, COSV64598090; called by muse, mutect2
- CACUL1 | c.282C>T p.C94= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs758215948, COSV100432496; called by muse, mutect2, varscan2
- CDKL5 | c.264G>C p.V88= | Silent (SNP) | VAF 29/138 reads (21%) | catalogued as COSV101184195; called by muse, mutect2, varscan2
- COA4 | c.150C>T p.D50= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV100142407; called by muse, mutect2
- DMD | c.6618A>G p.L2206= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100626617; called by muse, mutect2, varscan2
- FAT2 | c.5265T>C p.A1755= | Silent (SNP) | VAF 25/144 reads (17%) | catalogued as COSV99942247; called by muse, mutect2, varscan2
- LRRC3B | c.408G>A p.L136= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs916648869, COSV101185757; called by muse, mutect2, varscan2
- MN1 | c.2661C>T p.A887= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs1321981849, COSV100179740; called by muse, mutect2, varscan2
- MYH1 | c.5382G>A p.V1794= | Silent (SNP) | VAF 30/182 reads (16%) | catalogued as rs868151565, COSV99875405; called by muse, mutect2, varscan2
- NR5A2 | c.669A>G p.L223= (on ENST00000367362 / NM_205860.3; = p.L177= on NM_003822.5) | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as rs578158497, COSV99370934; called by muse, mutect2, varscan2
- NUP37 | c.561T>C p.N187= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV99195840; called by muse, mutect2, varscan2
- POTEA | c.1134C>T p.S378= (on ENST00000519951 / NM_001005365.2; = p.S332= on NM_001002920.1) | Silent (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- SLC1A4 | c.1203C>G p.L401= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV52236015; called by muse, mutect2
- TET2 | c.2943T>A p.I981= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV99482037; called by muse, mutect2, varscan2
- TTN | c.21699A>G p.K7233= (on ENST00000591111; = p.K6306= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/283 reads (9%) | catalogued as COSV59988470, COSV60115039; called by muse, mutect2
- USP6 | c.1230T>G p.R410= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV100003564; called by muse, mutect2, varscan2
- ZCWPW2 | c.903A>G p.G301= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV101074689; called by muse, mutect2, varscan2
- CES2 | c.-65C>A | 5'UTR (SNP) | VAF 9/94 reads (10%) | catalogued as COSV100399162; called by muse, mutect2, varscan2
- MIR541 | n.11A>G | RNA (SNP) | VAF 8/102 reads (8%) | catalogued as rs748290671; called by muse, mutect2
